Surgical pathology report (de-identified scan), TCGA case TCGA-21-1077, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1077-01A (Primary Tumor).

[page 1 of 5]
Clinical History/Diagnosis: Left Lung Mass

Source of Specimen(s):

- 1: Portion of left 6th rib
- 2: Level 6 lymph node
- 3: Level 11 lymph node
- 4: left upper lobe of lung
- 5: Level 5 lymph nodes
- 6: Level 6 lymph node
- 7: Level 7 lymph nodes
- 8: Anterior
- 9: Posterior
- 10: Superior mediastinal margin
- 11: Medial mediastinal
- 12: New bronchial margin
- 13: Second bronchial margin

Gross Description:

Received in thirteen parts.

Source of Tissue: 1. Labeled #1, "portion of left 6th rib"

Gross Description: Received fresh labeled "[REDACTED]" and "[REDACTED]" portion of left 6th rib" is a 1.5 cm in greatest dimension tan-pink fragment of rib having a minimal amount of attached soft tissue. It is entirely submitted in one block, following decalcification.

Designation of Sections: Block 1

Summary of Sections: undesignated-multiple

Source of Tissue: 2. Labeled #2, "level 6 lymph node"

Gross Description: Received fresh labeled "[REDACTED]" level 6 lymph node" is a 1.5 cm in greatest dimension focally anthracotic stained tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 2

Summary of Sections: undesignated-1

Source of Tissue: 3. Labeled #3, "level 11 lymph node"

[page 2 of 5]
Gross Description: Received fresh labeled " [REDACTED] level 11 lymph node" is a 0.8 cm gray-black anthracotic stained tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 3

Summary of Sections: undesignated-1

Source of Tissue: 4. Labeled # 4, "left upper lobe of lung"

Frozen Section Diagnosis: 4FA- POSITIVE BRONCHIAL MARGIN, 4FSB- ADHESIONS IN RELATIONSHIP TO LUNG TISSUE; PLEURA POSITIVE.

Gross Description: Received fresh for frozen section in a container labeled " [REDACTED] and [REDACTED], left upper lobe of lung". It consists of a 256 gram lobe of lung measuring 20.5 x 9.0 x 7.0 cm. The bronchial margin was procured for frozen section and the residue is in 4FSA. At the hilum, multiple grayish-black rubbery to firm lymph nodes are found measuring from 0.5 up to 1.6 cm. A few of the nodes at the superior aspect of the hilum are potentially involved by lesion. Upon opening of bronchial tree, a large superior branch is grossly involved by a mass. The bronchial tree in this area is obliterated by aforementioned mass. The pleural surface superiorly has multiple fibromembranous and fibroadipose adhesions and gross tumor is present involving the pleura and possibly the adhesions. Two representative sections from this area were selected for frozen section and the residue is in 4FSB. Sections in this area disclose firm tan tumor measuring 5.5 x 4.5 x 4.0 cm, involving the pleura and bronchial margin. Adjacent to the lesion there is some bronchiectasis. The tumor involves approximately 35% of the left upper lobe. Representative sections are submitted in 4A-K.

Designation of Sections: 4A- vascular margins, 4B-4C- lymph nodes, 4D-4F- additional sections from hilum [D is adjacent to the bronchial margin], 4G- pleura with adhesions, 4H- pleura with adhesions, 4I- additional section of left upper lobe lung tumor, 4J- uninvolved tissue adjacent to tumor, 4K- uninvolved tissue away from tumor

Source of Tissue: 5. Labeled #5, "level 5 lymph node"

Gross Description: Received fresh labeled " [REDACTED] level 5 lymph node" is a 2.0 x 1.0 x 0.5 cm yellow-tan focally anthracotic stained tissue fragment. It is entirely submitted in two blocks.

Designation of Sections: 5A-5B

Summary of Sections: multiple

Source of Tissue: 6. Labeled #6, "level 6 lymph node"

[page 3 of 5]
Gross Description: Received fresh labeled "[REDACTED] level 6 lymph node" is a 0.8 cm yellow-tan soft tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 6

Summary of Sections: undesignated-1

Source of Tissue: 7. Labeled #7, "level 7 lymph node"

Gross Description: Received fresh labeled "[REDACTED] level 7 lymph node" are three gray-black anthracotic stained lymph nodes with attached adipose tissue, 1.2 cm in greatest dimension. They are submitted in toto in one block.

Designation of Sections: Block 7

Summary of Sections: undesignated-3

Source of Tissue: 8. Labeled #8, "anterior mediastinal margin"

Gross Description: Received fresh labeled "[REDACTED] anterior mediastinal margin" is a 0.8 x 0.6 x 0.2 cm tan-pink soft tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 8

Summary of Sections: undesignated-1

Source of Tissue: 9. Labeled #9, "posterior mediastinal margin"

Gross Description: Received fresh labeled "[REDACTED] posterior mediastinal margin" is a 1.0 x 0.3 cm gray-tan soft tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 9

Summary of Sections: undesignated-1

Source of Tissue: 10. Labeled #10, "superior mediastinal margin"

Gross Description: Received fresh labeled "[REDACTED] superior mediastinal margin" is a 0.8 x 0.4 cm pink-red membranous soft tissue fragment which is submitted in toto in one block.

[page 4 of 5]
Designation of Sections: Block 10

Summary of Sections: undesignated-1

Source of Tissue: 11. Labeled #11, "medial mediastinal margin"

Gross Description: Received fresh labeled "[REDACTED] medial mediastinal margin" is a 1.5 x 0.8 x 0.2 cm yellow-tan fragment of soft tissue which is submitted in toto in one block.

Designation of Sections: Block 11

Summary of Sections: undesignated-1

Source of Tissue: 12. Labeled #12, "new bronchial margin"

Frozen Section Diagnosis: 12FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled "[REDACTED] new bronchial margin" is a 1.0 x 0.8 x 0.3 cm gray-tan fragment of lung. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 12FS

Summary of Sections: FS-1

Source of Tissue: 13. Labeled #13, "second bronchial margin"

Gross Description: Received fresh labeled "[REDACTED] second bronchial margin" is a 1.5 x 0.6 x 0.3 cm tan-pink fragment of bronchial mucosa. There are multiple staples present. These are removed and the remaining soft tissue is entirely submitted in one block.

Designation of Sections: Block 13

Summary of Sections: undesignated-multiple

Final Diagnosis:

1. Portion of 6th rib, resection:- No tumor seen.

2. Level 6 lymph node, biopsy:

[page 5 of 5]
- One lymph node with no tumor seen (0/1).

3. Level 11 lymph node, biopsy:

- One lymph node with no tumor seen (0/1).

4. Left lung upper lobe, lobectomy:

- Bronchiogenic squamous cell carcinoma, keratinizing, high grade (5.5 cm); tumor invades visceral pleura.

- In situ and invasive carcinoma involves bronchial margin (including peribronchial soft tissue); tumor is seen in a lymph node and perivascular soft tissue on a section of the vascular margin (slide 4A).

- Three of fifteen peribronchial lymph nodes positive for metastatic squamous cell carcinoma (3/15).

5. Level 5 lymph nodes, biopsy:- Seven lymph nodes with no tumor seen (0/7).

6. Level 6 lymph node, biopsy:

- One lymph node with no tumor seen (0/1).

7. Level 7 lymph node, biopsy:

- Three lymph nodes with no tumor seen (0/3).

8. Anterior mediastinal margin, biopsy:

- No tumor seen.

9. Posterior mediastinal margin, biopsy:

- No tumor seen.

10. Superior mediastinal margin, biopsy:

- No tumor seen.

11. Medial mediastinal margin, biopsy:

- No tumor seen.

12. New bronchial margin, biopsy:

- No tumor seen.

13. Second bronchial margin, biopsy:

- No tumor seen.

pT2N1Mx.

pTNM: T2 N1 Mx

Source: NCI Genomic Data Commons file 4959c4f1-7772-4775-9afe-6e9a290a30b5 (TCGA-21-1077.9313F5A4-32EF-4A20-890F-D437C24E2F8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).